Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NZ-01A (Primary Tumor).

[page 1 of 3]
105-0-3

Adenocarcinoma, endometrioid and villoglandular 8380/3

Site: Endometrium CS4.1

2/24/11 *hw*

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, hysterectomy: FIGO grade 1 (of 3) endometrial adenocarcinoma, endometrioid and villoglandular type, is identified

forming a mass (2.5 x 2.0 x 0.7 cm), located in the posterior

uterine wall. The tumor invades 0.6 cm into the myometrium (total

wall thickness 1.8 cm). Lymphovascular space invasion is not

identified. The tumor does not involve the endocervix.

The margins

are negative for tumor.

B. Fallopian tube, left, salpingectomy: The left fallopian tube is without diagnostic abnormality.

C. Ovary and fallopian tube, right, salpingo-oophorectomy: The

right ovary and fallopian tube are without diagnostic abnormality.

Frozen section histologic interpretation performed by:

, M.D.

D. Ovary, left, oophorectomy: The left ovary is without diagnostic abnormality.

E. Lymph nodes, right pelvic, lymphadenectomy: Multiple (12) right

pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

M.D.

F. Lymph nodes, left pelvic, lymphadenectomy: Multiple (22) left

[page 2 of 3]
pelvic lymph nodes are negative for tumor.

With available surgical material [AJCC pT1aN0] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 105.0 gram uterus without attached bilateral tubes and ovaries. The uterine serosa is disrupted and has diffuse fibrous adhesions. There is a 2.5 x 2.0 x 0.7 cm polypoid mass in the right side of the endometrial cavity without invasion grossly. The myometrial thickness is 1.8 cm. There are 3 uterine submucosal and intramural leiomyomata ranging from 0.3 cm to 1.9 cm. Representative sections are submitted.

B. Received fresh labeled "left fallopian tube" is an 8.0 cm in length by 0.4 cm in diameter portion of unremarkable fallopian tube.

Representative sections are submitted.

C. Received fresh labeled "right fallopian tube and ovary" is a

[page 3 of 3]
15.0 gram, 3.0 x 2.5 x 1.0 cm ovary with a 7.5 x 0.5 cm fallopian tube. The ovary has a smooth outer surface and a solid cut surface.

The fallopian tube unremarkable. Representative sections submitted.

D. Received fresh labeled "left ovary" is a 10.0 gram, 2.8 x 2.4 x

1.0 cm ovary. The ovary has a smooth outer surface and a solid cut

surface. Representative sections submitted.

E. Received fresh labeled "right pelvic nodes" is a 4.0 x 4.0 x 3.0

cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by . .

F. Received fresh labeled "left pelvic lymph nodes" is a 7.0 x 6.0

x 2.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes

submitted.

Source: NCI Genomic Data Commons file c00a4768-298f-41a1-b77a-ac8bad95f253 (TCGA-D1-A1NZ.0AFDCBC0-FA0A-4138-A0BE-E374AEB3CB25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).